Gene-level copy-number profile of tumor specimen TCGA-66-2783-01A from TCGA case TCGA-66-2783, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 67.6 years (24,686 days).
Specimen TCGA-66-2783-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.c6bc82cd-b3cc-463f-8047-d440b1139423.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-66-2783-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4f90b52b-ebbf-4e03-b5c9-b419914d6506

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 11,459; copy number 2: 39,424; copy number 3: 5,478; copy number 4: 1,419; copy number 5: 800; copy number 6: 62; copy number 7: 1,169; copy number 9: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-66-2783-01A-01D-1195-01): tumor purity 0.57, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,034 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,106,317–152,196,699, 4 genes, copy number 5: TCHH, AL589986.1, PUDPP2, RPTN.
- chr1:152,205,858–152,224,193, 2 genes, copy number 5: AL589986.2, HRNR.
- chr3:93,843,764–198,222,513, 1,800 genes, copy number 5–7 (broad region; genes not listed).
- chr6:69,866,556–71,127,105, 20 genes, copy number 5 (within-gene range 3–5): COL19A1, RPL37P15, COL9A1, AL160262.1, AL080275.1, AL365226.1, FAM135A-AS1, FAM135A, RNU7-48P, SDHAF4, AL583856.2, AL583856.1, SLC25A6P6, SMAP1, AL354943.1, NDUFAB1P1, B3GAT2, AL096709.1, BECN1P2, U3.
- chr17:50,094,737–50,112,152, 1 gene, copy number 6 (within-gene range 2–6): PDK2.
- chr17:50,110,040–50,397,523, 19 genes, copy number 6 (within-gene range 2–6): SAMD14, PPP1R9B, AC002401.1, AC015909.2, AC015909.3, SGCA, H1-9P, COL1A1, AC015909.1, AC015909.4, SUMO2P7, TMEM92, TMEM92-AS1, XYLT2, AC015909.5, MRPL27, EME1, LRRC59, Y_RNA.
- chr17:52,985,513–53,106,358, 2 genes, copy number 7: LINC02876, MTCO1P40.
- chr17:53,353,427–53,439,721, 3 genes, copy number 7: AC005341.1, AC090079.1, AC090079.2.
- chr17:57,255,851–57,684,689, 1 gene, copy number 7 (within-gene range 2–7): MSI2.
- chr17:57,448,218–57,618,393, 5 genes, copy number 7: AC015883.1, AC007431.2, AC007431.3, AC007431.1, RN7SL449P.
- chr17:63,773,603–63,989,422, 16 genes, copy number 6 (within-gene range 2–6): DDX42, FTSJ3, PSMC5, SMARCD2, TCAM1P, CSH2, GH2, AC040958.1, CSH1, AC127029.1, CSHL1, GH1, AC127029.3, CD79B, SCN4A, AC127029.2.
- chr17:67,377,281–67,697,261, 1 gene, copy number 5 (within-gene range 2–5): PITPNC1.
- chr17:67,457,023–68,422,731, 35 genes, copy number 5 (within-gene range 2–5): RN7SL756P, MIR548AA2, MIR548D2, AC110921.1, AC079331.2, AC079331.1, AC079331.3, NOL11, SNORA38B, RPSAP67, RPL17P41, BPTF, AC134407.1, AC134407.2, AC134407.3, RN7SL622P, C17orf58, KPNA2, FBXO36P1, AC145343.1, LINC00674, LRRC37A16P, AC005332.6, AC005332.3, AC005332.5, SH3GL1P3, RDM1P3, AC005332.7, AC005332.2, ARHGAP27P2, AC005332.4, AMZ2, AC005332.1, ARSG, SLC16A6.
- chr17:71,678,899–71,743,468, 1 gene, copy number 6: AC007432.1.
- chr17:75,441,159–75,905,093, 25 genes, copy number 6 (within-gene range 2–6): TMEM94, MIR6785, CASKIN2, TSEN54, LLGL2, MYO15B, RECQL5, SMIM5, SMIM6, SAP30BP, AC087749.2, AC087749.1, ITGB4, GALK1, H3-3B, MIR4738, UNK, AC087289.1, UNC13D, WBP2, TRIM47, AC087289.5, TRIM65, AC087289.2, MRPL38.
- chr17:76,735,865–76,781,449, 1 gene, copy number 5 (within-gene range 3–5): MFSD11.
- chr17:76,752,912–77,099,902, 10 genes, copy number 5 (within-gene range 2–5): RNU6-97P, LINC02080, AC016168.4, LINC00868, MGAT5B, AC016168.2, AC016168.1, AC016168.3, Metazoa_SRP, SNHG20.
- chr17:77,089,307–77,089,497, 2 genes, copy number 5: SCARNA16, MIR6516.
- chr17:77,590,532–78,173,527, 13 genes, copy number 7 (within-gene range 2–7): AC021683.5, LINC01987, LINC01973, RNU1-80P, TNRC6C, AC015804.1, UBE2V2P2, RNU6-625P, TMC6, TMC8, C17orf99, EIF5AP2, SYNGR2.
- chr17:82,273,748–82,644,662, 24 genes, copy number 5 (within-gene range 1–5): AC132872.5, LINC01970, AC132872.1, CD7, SECTM1, TEX19, AC132938.4, UTS2R, AC132938.1, OGFOD3, AC132938.2, Y_RNA, HEXD, HEXD-IT1, CYBC1, AC132938.6, AC132938.3, NARF, AC132938.5, NARF-AS1, NARF-IT1, FOXK2, AC124283.4, AC124283.3.
- chr18:47,390–812,546, 28 genes, copy number 5–9: TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078, USP14, THOC1, AP000845.1, AP000915.1, COLEC12, AP000915.2, LINC01925, CETN1, RN7SKP146, CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS, ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P.
- chr20:142,590–675,802, 21 genes, copy number 5: DEFB126, DEFB127, DEFB128, DEFB129, DEFB132, AL034548.1, C20orf96, ZCCHC3, AL034548.2, NRSN2-AS1, SOX12, NRSN2, TRIB3, RBCK1, TBC1D20, Y_RNA, CSNK2A1, TCF15, SRXN1, AL121758.1, SCRT2.

Autosomal genes at a single copy (total copy number 1): 9,080. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
